Gene-level copy-number profile of tumor specimen ALCH-ADXK-TTP1-A from ALCHEMIST case ALCH-ADXK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.8 years (21,128 days).
Specimen ALCH-ADXK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c9fc0d38-82b4-4cca-9d89-d4ad240f7238.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADXK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/6c4cd477-1e6d-4778-8013-8739f4a2071a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 418; copy number 1: 22,717; copy number 2: 28,828; copy number 3: 5,325; copy number 4: 1,110; copy number 5: 51; copy number 6: 5; copy number 7: 348; copy number 9: 1; copy number 10: 4; copy number 13: 31; copy number 15: 3; copy number 16: 20; copy number 18: 13; copy number 19: 37.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:121,049,640–121,099,774, 2 genes (within-gene range 0–1): MIR5682, AC078857.1.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr8:43,672,823–46,028,892, 3 genes: AC139365.2, AC139365.1, AC118650.1.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr12:38,078,529–38,087,392, 2 genes: AK6P2, CLUHP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 513 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:117,031,200–117,038,569, 1 gene, copy number 5: AC093534.2.
- chr5:151,029,945–151,224,093, 4 genes, copy number 5–6 (within-gene range 4–6): TNIP1, ANXA6, AC008641.1, CCDC69.
- chr7:65,751,142–67,770,468, 64 genes, copy number 7 (broad region; genes not listed).
- chr7:91,692,008–99,504,857, 149 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:100,088,969–103,989,658, 162 genes, copy number 7–13 (broad region; genes not listed).
- chr8:122,485,194–123,589,046, 37 genes, copy number 19: LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155.
- chr8:127,289,817–128,564,679, 20 genes, copy number 16: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:133,886,496–133,963,259, 3 genes, copy number 15: AC110741.1, AC110741.3, AC110741.2.
- chr8:138,588,235–138,914,041, 1 gene, copy number 9: COL22A1.
- chr13:83,877,205–86,170,890, 13 genes, copy number 18: SLITRK1, AL355481.1, VENTXP2, UBE2D3P4, MTND4P1, MTND5P3, LINC00333, LINC00375, LINC00351, SLITRK6, AL162373.1, MOB1AP1, AL354994.1.
- chr18:58,044,226–58,477,484, 9 genes, copy number 5–10: NEDD4L, AC107896.1, AC090236.2, AC090236.1, AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4.
- chr18:62,415,678–62,587,709, 6 genes, copy number 5–6: RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2.
- chr18:67,081,584–70,384,591, 44 genes, copy number 5: MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P, TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3, AC096708.1, AC090337.1, AC026585.1, DOK6, AC119868.1, AC119868.2, AC068254.2, AC068254.1, CD226, RTTN, AC021701.1, SOCS6, LINC01909, LIVAR, LINC01910.

Autosomal genes at a single copy (total copy number 1): 20,263. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
